Somatic mutation profile of tumor specimen TCGA-CN-A498-01A (aliquot TCGA-CN-A498-01A-11D-A24D-08) from TCGA case TCGA-CN-A498, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 61.1 years (22,330 days).
Specimen TCGA-CN-A498-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d973f5c1-6fb4-4853-b5cd-3fc90a3d3bc1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-A498-10A (Blood Derived Normal), aliquot TCGA-CN-A498-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/beacfea8-3b1e-4cfd-af3f-e3b7bd3fab32

The open-access MAF lists 127 somatic variants for this specimen: 98 protein-altering or splice-affecting, 23 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 23, Nonsense Mutation 11, Frame Shift Del 3, Frame Shift Ins 2, 3'UTR 2, RNA 2, Splice Site 1, 5'UTR 1, Translation Start Site 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.2077C>T p.R693* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as rs373221034, COSV60102332; ClinVar: pathogenic; called by muse, mutect2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 24/143 reads (17%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.298); catalogued as rs771879279, COSV100216944; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3042A>T p.E1014D | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1283187655, COSV99717853; called by muse, mutect2, varscan2
- ADSS2 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV100836824; called by muse, mutect2, varscan2
- ALDH3A2 | c.164A>G p.N55S | Missense Mutation (SNP) | VAF 55/104 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs749090236, COSV99449735; called by muse, mutect2, varscan2
- AMACR | c.132C>G p.S44R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV100162958; called by muse, mutect2, varscan2
- AMY2A | c.190G>A p.V64I | Missense Mutation (SNP) | VAF 40/159 reads (25%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV101340625; called by muse, mutect2, varscan2
- ASH1L | c.5588C>G p.S1863* | Nonsense Mutation (SNP) | VAF 27/164 reads (16%) | catalogued as COSV64215242; called by muse, mutect2, varscan2
- ATP2B4 | c.168T>A p.S56R | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100397323; called by muse, mutect2, varscan2
- BAG5 | c.590G>A p.R197Q | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.652); catalogued as rs748217159, COSV54570867; called by muse, mutect2, varscan2
- BAIAP3 | c.1979C>T p.S660L | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs374379669; called by muse, mutect2, varscan2
- C3 | c.2800G>A p.E934K | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV55583580; called by muse, mutect2, varscan2
- CCNB3 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.063); catalogued as COSV99328770; called by muse, mutect2, varscan2
- CDHR3 | c.2091T>A p.Y697* | Nonsense Mutation (SNP) | VAF 4/25 reads (16%) | catalogued as COSV100488152; called by muse, mutect2, varscan2
- CHD1 | c.3458G>A p.R1153Q | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.056); catalogued as COSV99399285; called by muse, mutect2, varscan2
- CLASP1 | c.3132G>T p.Q1044H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55331383; called by muse, mutect2
- CNTNAP4 | c.3734G>A p.G1245D | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1227449682, COSV100270377; called by muse, mutect2, varscan2
- CYP39A1 | c.1399C>T p.Q467* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99242062; called by muse, mutect2, varscan2
- DCAF8L1 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101491429; called by muse, mutect2, varscan2
- DCHS1 | c.2251C>T p.R751W | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs759188370, COSV55032458; called by muse, mutect2
- DMD | c.2306A>G p.E769G | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.363); catalogued as COSV100818875; called by muse, mutect2, varscan2
- DNAH5 | c.13313C>A p.A4438D | Missense Mutation (SNP) | VAF 63/224 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99447435; called by muse, mutect2, varscan2
- DNAI1 | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs150107677; called by mutect2, varscan2
- EEPD1 | c.520G>A p.V174I | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV99632021; called by muse, mutect2, varscan2
- ERAP2 | c.2326C>T p.Q776* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV101163587; called by muse, mutect2, varscan2
- FLT4 | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); catalogued as rs753792784, COSV56098916, COSV99986433; called by muse, mutect2, varscan2
- GPC6 | c.1531G>C p.E511Q | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.351); catalogued as rs1030771443, COSV100988301; called by muse, mutect2, varscan2
- GRM7 | c.964C>G p.P322A | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100735781, COSV100736033; called by muse, mutect2, varscan2
- GTF2F1 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.14); catalogued as rs377173937; called by muse, mutect2, varscan2
- GULP1 | c.154A>T p.K52* | Nonsense Mutation (SNP) | VAF 21/82 reads (26%) | catalogued as COSV100770429; called by muse, mutect2, varscan2
- HACL1 | c.220A>G p.T74A | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100337173; called by muse, mutect2
- IFITM3 | c.5A>G p.N2S | Missense Mutation (SNP) | VAF 9/189 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as rs1228855688; called by muse, mutect2
- KDM5C | c.2010G>T p.M670I | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV100948968; called by muse, mutect2, varscan2
- KMT2C | c.6263A>G p.N2088S | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs773701046, COSV100069641, COSV51277929; called by muse, mutect2, varscan2
- KRT20 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs147567550; called by muse, mutect2, varscan2
- LEPR | c.2925G>T p.E975D | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.057); catalogued as COSV100848063, COSV62745612; called by muse, mutect2, varscan2
- LHX9 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 15/78 reads (19%) | catalogued as COSV100435737; called by muse, mutect2, varscan2
- MAP3K12 | c.1738C>A p.L580I | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV99913108; called by muse, mutect2, varscan2
- MED12 | c.4076C>A p.S1359Y | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100377043, COSV100377163; called by muse, mutect2, varscan2
- MT1H | c.37T>C p.C13R | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV100189960; called by muse, mutect2, varscan2
- MUC5B | c.10992C>G p.F3664L | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV101500192, COSV101500700; called by muse, mutect2, varscan2
- NAA60 | c.98G>T p.W33L | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.177); catalogued as COSV100692763; called by muse, mutect2, varscan2
- NAP1L3 | c.880G>C p.D294H | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV100220263, COSV59075243; called by muse, mutect2, varscan2
- NLGN3 | c.2290G>A p.A764T (on ENST00000358741 / NM_181303.2; = p.A744T on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.028); catalogued as COSV100704622; called by muse, mutect2, varscan2
- NOL8 | c.71T>C p.L24P | Missense Mutation (SNP) | VAF 55/106 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100694497; called by muse, mutect2, varscan2
- NOTCH2 | c.4351G>C p.D1451H | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56700238, COSV99863436; called by muse, mutect2, varscan2
- NRDC | c.1643+1G>A p.X548_splice | Splice Site (SNP) | VAF 15/72 reads (21%) | catalogued as COSV100703252; called by muse, mutect2, varscan2
- OR5A1 | c.187T>A p.Y63N | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100118326; called by muse, mutect2, varscan2
- OR6C65 | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.113); catalogued as COSV101110175, COSV99059233; called by muse, mutect2, varscan2
- PABPC3 | c.1183C>G p.Q395E | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.09); catalogued as COSV99879287; called by muse, varscan2
- PARP4 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs199585627, COSV67962766; called by muse, mutect2, varscan2
- PCLO | c.2732G>A p.S911N | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as COSV100429876; called by muse, mutect2, varscan2
- PDE1B | c.366C>A p.F122L | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.994); catalogued as COSV99672347; called by muse, mutect2, varscan2
- PNMA2 | c.215A>C p.D72A | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.062); catalogued as COSV101580606; called by muse, mutect2, varscan2
- POLR2E | c.319C>T p.Q107* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as COSV99297472; called by muse, mutect2, varscan2
- POU2F2 | c.601G>A p.E201K (on ENST00000526816 / NM_001207025.3; = p.E185K on NM_002698.5) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60763492; called by muse, mutect2, varscan2
- PRDM2 | c.3376G>T p.V1126F | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as COSV99341251; called by muse, mutect2, varscan2
- PRIM1 | c.832A>G p.R278G | Missense Mutation (SNP) | VAF 59/229 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV100590354; called by muse, mutect2, varscan2
- RAVER2 | c.1399G>C p.E467Q (on ENST00000294428 / NM_001366165.1; = p.E454Q on NM_018211.4) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.963); catalogued as COSV99604999; called by muse, mutect2, varscan2
- RIMS2 | c.4722A>C p.R1574S (on ENST00000666250 / NM_001348490.2; = p.R1145S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99165436; called by muse, mutect2
- RS1 | c.457G>T p.V153L | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.56); PolyPhen benign (0.015); catalogued as COSV101183761; called by muse, mutect2, varscan2
- SCN3A | c.1411G>C p.D471H | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); catalogued as COSV51806574, COSV99326342; called by muse, mutect2
- SEL1L2 | c.1435T>C p.W479R | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99532921; called by muse, mutect2, varscan2
- SERPINA10 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV56229814; called by muse, mutect2, varscan2
- SLCO3A1 | c.2084A>G p.Y695C | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.751); catalogued as COSV100575151; called by muse, mutect2, varscan2
- SORCS1 | c.1336G>A p.V446I | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.085); catalogued as rs1463344858, COSV53898211, COSV99544827; called by muse, mutect2, varscan2
- SPCS1 | c.321C>A p.Y107* (on ENST00000233025; = p.Y40* on NM_014041.5) | Nonsense Mutation (SNP) | VAF 51/153 reads (33%) | catalogued as COSV99236807; called by muse, mutect2, varscan2
- SYNE1 | c.14242C>A p.Q4748K (on ENST00000367255 / NM_182961.4; = p.Q4677K on NM_033071.3) | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.033); catalogued as COSV99558379; called by muse, mutect2, varscan2
- SYNE1 | c.6038C>T p.A2013V (on ENST00000367255 / NM_182961.4; = p.A2020V on NM_033071.3) | Missense Mutation (SNP) | VAF 64/270 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV99558382; called by muse, mutect2, varscan2
- TCEAL7 | c.127C>T p.Q43* | Nonsense Mutation (SNP) | VAF 23/65 reads (35%) | catalogued as COSV100197092; called by muse, mutect2, varscan2
- TGFB2 | c.188T>G p.V63G | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.182); catalogued as COSV100859998; called by muse, mutect2, varscan2
- THEMIS2 | c.1852G>A p.A618T (on ENST00000373921 / NM_001286115.1; = p.R260H on NM_004848.3) | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs147739833; called by muse, mutect2, varscan2
- THSD7A | c.3431A>G p.Y1144C | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.976); catalogued as rs1300160689, COSV101439734; called by muse, mutect2, varscan2
- TMEM218 | c.173C>A p.P58Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99692553; called by muse, mutect2, varscan2
- TMEM60 | c.82G>C p.D28H | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51896343, COSV99301363; called by muse, varscan2
- TMEM60 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 14/51 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV99301365; called by muse, varscan2
- TP53 | c.890del p.H297Pfs*48 | Frame Shift Del (DEL) | VAF 25/66 reads (38%) | catalogued as COSV52864048, COSV53170241; called by mutect2, pindel, varscan2
- TRPC1 | c.1694C>T p.S565L (on ENST00000476941 / NM_001251845.2; = p.S531L on NM_003304.4) | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV99858472; called by muse, mutect2
- UMODL1 | c.1370C>G p.S457C | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1367039461, COSV100210642; called by muse, mutect2, varscan2
- USP24 | c.7828G>A p.E2610K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.074); catalogued as rs752787485, COSV99599248; called by muse, mutect2, varscan2
- XRN1 | c.1552C>G p.L518V | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99377607; called by muse, mutect2, varscan2
- ZFHX4 | c.6908G>A p.R2303Q | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1231236679, COSV99260302, COSV99269355; called by muse, mutect2, varscan2
- ZFHX4 | c.7921G>A p.E2641K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1306899927, COSV50510794; called by muse, mutect2, varscan2
- ZFP64 | c.1820C>T p.S607L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.267); catalogued as COSV53796400; called by muse, mutect2, varscan2
- ZNF273 | c.572C>T p.S191L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV100139223, COSV60397400; called by muse, mutect2, varscan2
- ZNF560 | c.2295G>T p.E765D | Missense Mutation (SNP) | VAF 25/100 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.748); catalogued as COSV100038403; called by muse, mutect2, varscan2
- ZNF695 | c.400T>A p.W134R | Missense Mutation (SNP) | VAF 70/329 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100377358; called by muse, mutect2, varscan2
- ZNF783 | c.413C>A p.A138D | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV100954203; called by muse, mutect2
- ZXDB | c.2345C>T p.A782V | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.061); catalogued as COSV66493608; called by muse, mutect2, varscan2
- ADORA2A | c.302_313del p.D101_I104del | In Frame Del (DEL) | VAF 16/70 reads (23%) | called by mutect2, pindel, varscan2
- IGHV1-69 | c.276C>A p.D92E | Missense Mutation (SNP) | VAF 56/227 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- ITGA1 | c.769G>A p.A257T | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.47); called by muse, mutect2
- ITPR2 | c.6458_6491del p.R2153Lfs*30 | Frame Shift Del (DEL) | VAF 17/99 reads (17%) | called by mutect2, pindel
- MUC5B | c.12095C>A p.T4032N | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.066); called by mutect2, varscan2
- MYRIP | c.1211dup p.S404Rfs*2 | Frame Shift Ins (INS) | VAF 24/71 reads (34%) | called by mutect2, pindel, varscan2
- NYNRIN | c.4410dup p.A1471Cfs*15 | Frame Shift Ins (INS) | VAF 5/46 reads (11%) | called by mutect2, pindel, varscan2
- SLITRK2 | c.1594del p.D532Tfs*9 | Frame Shift Del (DEL) | VAF 20/102 reads (20%) | called by mutect2, pindel, varscan2
- CFP | c.669G>A p.K223= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as COSV99901384; called by muse, mutect2, varscan2
- CNDP2 | c.19C>T p.L7= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV100159044, COSV100159159; called by muse, mutect2, varscan2
- CRISP1 | c.741G>A p.E247= | Silent (SNP) | VAF 33/173 reads (19%) | catalogued as COSV100236734; called by muse, mutect2, varscan2
- ENTPD6 | c.1272G>A p.Q424= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100737028; called by muse, mutect2, varscan2
- FAM131A | c.381C>G p.L127= (on ENST00000310585; = p.L158= on NM_144635.5) | Silent (SNP) | VAF 21/126 reads (17%) | catalogued as COSV99658393; called by muse, mutect2, varscan2
- FAM186B | c.2229C>T p.A743= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as rs200823605, COSV99218413; called by muse, mutect2, varscan2
- GPR158 | c.1623C>A p.L541= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV66267539; called by muse, mutect2, varscan2
- KCNT2 | c.552A>T p.L184= | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- KDM1B | c.78C>T p.S26= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs1361710101, COSV99924102; called by muse, mutect2, varscan2
- LTBP4 | c.2826C>T p.F942= (on ENST00000308370 / NM_001042544.1; = p.F905= on NM_003573.2) | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- MYH10 | c.1809G>A p.V603= | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as COSV99344643; called by muse, mutect2, varscan2
- PTPRC | c.3165C>G p.V1055= | Silent (SNP) | VAF 22/143 reads (15%) | catalogued as COSV100722336, COSV61409314; called by muse, mutect2, varscan2
- RNF10 | c.2050C>T p.L684= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV100378552; called by muse, mutect2, varscan2
- SLCO4C1 | c.585C>T p.F195= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as COSV60516537; called by muse, mutect2, varscan2
- SPICE1 | c.1968G>A p.L656= | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as COSV99871158; called by muse, mutect2, varscan2
- SULT4A1 | c.294C>T p.I98= | Silent (SNP) | VAF 40/112 reads (36%) | catalogued as COSV99970552; called by muse, mutect2, varscan2
- TASOR | c.4377A>G p.V1459= (on ENST00000355628 / NM_001365636.2; = p.V1083= on NM_015224.3) | Silent (SNP) | VAF 20/73 reads (27%) | catalogued as rs774785004, COSV100413826; called by muse, mutect2, varscan2
- TAZ | c.634C>T p.L212= | Silent (SNP) | VAF 38/141 reads (27%) | catalogued as rs587781186, CD972178, COSV100173277; ClinVar: benign; called by muse, mutect2, varscan2
- TPH2 | c.780C>G p.L260= | Silent (SNP) | VAF 63/255 reads (25%) | catalogued as COSV100421984; called by muse, mutect2, varscan2
- USP34 | c.1185G>A p.L395= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as COSV101276854, COSV68407077; called by muse, mutect2, varscan2
- ZNF20 | c.1224T>G p.S408= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV100502943; called by muse, mutect2, varscan2
- ZNF28 | c.186G>C p.G62= | Silent (SNP) | VAF 47/222 reads (21%) | catalogued as COSV100354382; called by muse, mutect2, varscan2
- ZNF578 | c.1632T>C p.C544= | Silent (SNP) | VAF 27/103 reads (26%) | catalogued as COSV101405028; called by muse, mutect2, varscan2
- AARS2 | c.-2C>A | 5'UTR (SNP) | VAF 4/9 reads (44%) | catalogued as COSV99771340; called by muse, mutect2
- BACH1-IT1 | n.36C>G | RNA (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- BBS10 | c.*2A>G | 3'UTR (SNP) | VAF 11/28 reads (39%) | catalogued as COSV101283366; called by muse, mutect2
- CEP295 | chr11:93733674 T>CC | 3'Flank (INS) | VAF 5/59 reads (8%) | called by mutect2*, pindel
- CTTN | c.*1129C>T | 3'UTR (SNP) | VAF 280/337 reads (83%) | catalogued as COSV100096931; called by muse, mutect2, varscan2
- MIR515-2 | n.71T>C | RNA (SNP) | VAF 14/48 reads (29%) | called by muse, varscan2
